Gene-level copy-number profile of tumor specimen CDDP-ACMK-TTP1-A from CDDP_EAGLE case CDDP-ACMK, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69 years.
Specimen CDDP-ACMK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09ac53f0-9a97-4eef-bd05-1f4e20cce6d0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACMK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/7deb499b-76a1-4ef9-be49-ac9ff7ab5b30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 11,495; copy number 2: 44,021; copy number 3: 2,968; copy number 4: 358; copy number 5: 39; copy number 6: 5; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,306,636–3,310,096, 1 gene (within-gene range 0–1): AL590438.1.
- chr8:24,169,001–24,177,080, 1 gene: AC023202.1.
- chr9:134,317,098–134,440,585, 2 genes: RXRA, MIR4669.
- chr9:134,992,958–134,995,854, 1 gene: AL353611.2.
- chr15:70,047,790–70,198,509, 4 genes: TLE3, MIR629, RNU6-745P, AC026583.1.
- chr20:23,071,547–23,086,324, 2 genes: AL118508.3, CD93.
- chr20:23,918,538–23,928,954, 1 gene: CSTP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,259,518–28,282,491, 1 gene, copy number 5: SESN2.
- chr1:150,282,543–150,629,612, 18 genes, copy number 5: CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4.
- chr3:196,341,609–196,341,715, 1 gene, copy number 5: RNU6-910P.
- chr7:74,773,962–74,789,376, 1 gene, copy number 13: NCF1.
- chr7:102,327,256–102,356,444, 4 genes, copy number 5: AC091390.1, Y_RNA, PMS2P12, SPDYE6.
- chr10:43,420,738–43,483,181, 3 genes, copy number 5: AL450326.1, ZNF487, RNU7-193P.
- chr11:62,602,218–62,612,775, 2 genes, copy number 6 (within-gene range 4–6): EML3, AP001458.1.
- chr20:58,981,208–59,516,039, 12 genes, copy number 5–6: NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1.
- chr20:63,956,704–64,033,100, 3 genes, copy number 5 (within-gene range 3–5): ZNF512B, SAMD10, PRPF6.

Autosomal genes at a single copy (total copy number 1): 8,684. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
